Somatic mutation profile of tumor specimen TARGET-10-PAPHRV-09A (aliquot TARGET-10-PAPHRV-09A-01D) from TARGET case TARGET-10-PAPHRV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,226 days).
Specimen TARGET-10-PAPHRV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 489ccb35-af46-42c9-8538-9903b323cab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHRV-10A (Blood Derived Normal), aliquot TARGET-10-PAPHRV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc0bb786-214b-49f3-965f-58e3a25dd879

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Splice Site 2, Nonsense Mutation 2, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXDND1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs902240096, COSV62641099; called by muse, mutect2, varscan2
- CRB1 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV66330931; called by muse, mutect2
- DYNC2H1 | c.10020G>C p.L3340F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1289083464, COSV62087556; called by muse, mutect2, varscan2
- EBF4 | c.142G>A p.V48M (on ENST00000609451; = p.V44M on NM_001110514.1) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs749337026; called by muse, mutect2, varscan2
- EPHA3 | c.970+2T>G p.X324_splice | Splice Site (SNP) | VAF 46/217 reads (21%) | catalogued as COSV60701087; called by muse, mutect2, varscan2
- MCC | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as rs1330328071; called by muse, mutect2
- PTPN14 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768464771; called by muse, mutect2, varscan2
- SULF2 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967263459, COSV100737504, COSV63415105, COSV63415152; called by muse, mutect2
- TBC1D32 | c.3097G>C p.D1033H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV51547116; called by muse, mutect2
- WDR90 | c.3841C>T p.R1281C | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs529912139; called by muse, mutect2, varscan2
- AOX1 | c.3344G>T p.S1115I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- B3GNT2 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- B4GALT5 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP57 | c.3127-2A>G p.X1043_splice (on ENST00000372492 / NM_001378189.1; = p.X1076_splice on NM_001195831.3) | Splice Site (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- DLX4 | c.369C>G p.I123M (on ENST00000240306 / NM_138281.3; = p.I51M on NM_001934.3) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IGLV3-12 | c.345_347dup | In Frame Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- MFSD1 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PIBF1 | c.1562C>G p.S521* | Nonsense Mutation (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- WASL | c.1042C>G p.P348A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FBLN2 | c.612C>T p.A204= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as rs752247665; called by muse, mutect2
- FRY | c.6582G>A p.T2194= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs375289926; called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031471 del CAC | Silent (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel*, varscan2
- ARL14EPL | c.-3G>A | 5'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, varscan2
